Somatic mutation profile of tumor specimen ALCH-ADO4-TTP1-B (aliquot ALCH-ADO4-TTP1-B-1-0-D-A549-36) from ALCHEMIST case ALCH-ADO4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.2 years (24,918 days).
Specimen ALCH-ADO4-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd7e1f35-1f77-4d2e-b30b-d53ecdab1ef4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADO4-NB1-A (Blood Derived Normal), aliquot ALCH-ADO4-NB1-A-1-0-D-A549-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c1c2770-fe76-471e-a437-10efb96869d5

The open-access MAF lists 197 somatic variants for this specimen: 136 protein-altering or splice-affecting, 43 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 43, Nonsense Mutation 13, Intron 12, Frame Shift Del 4, 3'UTR 2, RNA 2, Splice Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 23/171 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760640852, CM045607, COSV58683415, COSV58688841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD30B | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753495539; called by muse, mutect2, varscan2
- ATXN7L3 | c.200C>G p.P67R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV66989651; called by muse, mutect2, varscan2
- BBS12 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 75/444 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100045109; called by muse, mutect2, varscan2
- BRINP3 | c.1060C>A p.R354S | Missense Mutation (SNP) | VAF 85/562 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as rs200210126; called by muse, varscan2
- C1orf116 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV63944028; called by muse, mutect2
- COL11A1 | c.3233G>A p.G1078E | Missense Mutation (SNP) | VAF 25/588 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618352; called by muse, mutect2
- COL5A3 | c.4576G>T p.E1526* | Nonsense Mutation (SNP) | VAF 53/164 reads (32%) | catalogued as COSV53408410; called by muse, mutect2, varscan2
- CSMD3 | c.6031G>T p.G2011* (on ENST00000297405 / NM_001363185.1; = p.G1907* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 116/492 reads (24%) | catalogued as COSV52130319; called by muse, varscan2
- EFHC1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 60/474 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV64135573; called by muse, varscan2
- FASTKD2 | c.1600A>T p.M534L | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99379276; called by muse, varscan2
- GPR161 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs750197990; called by muse, mutect2, varscan2
- GPR78 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.804); catalogued as rs776487497; called by muse, mutect2, varscan2
- HMCN2 | c.4186G>A p.E1396K | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs957131602; called by muse, mutect2, varscan2
- HMGCLL1 | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 44/141 reads (31%) | catalogued as rs770679829; called by muse, varscan2
- ICE1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 44/436 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56824252; called by muse, varscan2
- IGLV3-1 | c.277A>T p.I93F | Missense Mutation (SNP) | VAF 78/491 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs548457166; called by muse, mutect2, varscan2
- IQSEC2 | c.2909G>A p.R970H (on ENST00000642864 / NM_001111125.3; = p.R765H on NM_015075.2) | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1556860937, COSV64724717; ClinVar: uncertain significance; called by muse, mutect2
- ITGAX | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.822); catalogued as rs867400184, COSV51641108; called by muse, mutect2, varscan2
- KCNA10 | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 87/254 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV63904702; called by muse, mutect2, varscan2
- KCNIP1 | c.380C>T p.S127L (on ENST00000411494 / NM_001034837.3; = p.S116L on NM_014592.4) | Missense Mutation (SNP) | VAF 28/501 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1257405253, COSV61082856; called by muse, mutect2
- KIAA1328 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1406673401; called by muse, mutect2, varscan2
- KIF13B | c.2988G>T p.L996F | Missense Mutation (SNP) | VAF 130/460 reads (28%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.823); catalogued as rs1171074566; called by muse, mutect2, varscan2
- KLHL30 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.306); catalogued as COSV100014602; called by muse, mutect2, varscan2
- LRP2 | c.10703C>T p.P3568L | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs753477259, COSV55540802; ClinVar: uncertain significance; called by muse, mutect2
- MEOX2 | c.764G>C p.R255P | Missense Mutation (SNP) | VAF 66/782 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs766976920; called by muse, mutect2
- MPP6 | c.5A>T p.Q2L | Missense Mutation (SNP) | VAF 126/265 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56035223; called by muse, mutect2, varscan2
- MUC16 | c.26196G>T p.M8732I | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.033); catalogued as COSV67480541; called by muse, mutect2
- MXRA5 | c.6992G>T p.G2331V | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54226450; called by muse, mutect2, varscan2
- NTRK3 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 67/543 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as rs374069724, COSV58112733; called by muse, mutect2, varscan2
- OBSCN | c.16322G>T p.R5441L | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV52777886; called by muse, mutect2, varscan2
- OR52R1 | c.796C>A p.R266S | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs186758176, COSV99049357; called by muse, mutect2, varscan2
- OVGP1 | c.1657C>G p.Q553E | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV63859090; called by muse, mutect2, varscan2
- PDE5A | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778846944; called by muse, mutect2
- PKD2L2 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as rs748627739; called by muse, mutect2
- QPRT | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1393968772; called by muse, mutect2, varscan2
- RNASE12 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 97/618 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as rs764405769, COSV60088151; called by muse, mutect2, varscan2
- RYR3 | c.7649A>T p.H2550L (on ENST00000389232; = p.H2551L on NM_001036.6) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV66796135; called by muse, varscan2
- S100PBP | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs755228540; called by muse, mutect2, varscan2
- SERPINA4 | c.248C>A p.S83* | Nonsense Mutation (SNP) | VAF 28/239 reads (12%) | catalogued as rs151234180; called by muse, mutect2, varscan2
- SLURP1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs752253252, COSV55816549; ClinVar: uncertain significance; called by muse, mutect2
- STOM | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 42/766 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs1054955040; called by muse, mutect2
- TAF3 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs1364700503; called by muse, mutect2
- THRA | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs201283167, COSV99225794; called by muse, mutect2, varscan2
- TP53 | c.323del p.G108Vfs*15 | Frame Shift Del (DEL) | VAF 46/156 reads (29%) | catalogued as COSV53329872; called by mutect2, pindel, varscan2
- TRPC6 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 189/863 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs267602664, CM156589, CM158444, COSV60251176; called by muse, mutect2, varscan2
- TRPM5 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868645318; called by muse, mutect2, varscan2
- TRPM5 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1036969415; called by muse, mutect2, varscan2
- URB1 | c.5137G>A p.D1713N | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66959041; called by muse, mutect2, varscan2
- USP40 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as rs900511222, COSV52483612; called by muse, mutect2, varscan2
- WDR81 | c.1656del p.K552Nfs*87 | Frame Shift Del (DEL) | VAF 51/184 reads (28%) | catalogued as COSV58478186; called by mutect2, pindel, varscan2
- ZFHX4 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 17/668 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs965677460; called by muse, mutect2
- ZNF10 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 48/140 reads (34%) | catalogued as COSV50212489; called by muse, mutect2, varscan2
- ZNF560 | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 24/218 reads (11%) | catalogued as rs763677471, COSV100039018, COSV56868329; called by muse, mutect2, varscan2
- ACOT12 | c.1430C>A p.P477Q | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ADAMTS16 | c.3024G>T p.K1008N | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- AKAP9 | c.3457G>T p.A1153S | Missense Mutation (SNP) | VAF 217/468 reads (46%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ART5 | c.658C>G p.R220G | Missense Mutation (SNP) | VAF 103/281 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- BMP4 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 20/620 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BNC1 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, varscan2
- BSN | c.9898G>T p.G3300W | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BSX | c.599C>G p.A200G | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNG2 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 146/577 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CCDC27 | c.103A>T p.S35C | Missense Mutation (SNP) | VAF 102/492 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CDH20 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CDON | c.3787G>A p.E1263K (on ENST00000392693 / NM_001243597.2; = p.E1240K on NM_016952.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/476 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CFAP54 | c.6790C>G p.L2264V | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); called by muse, mutect2
- CFAP65 | c.4935G>C p.K1645N | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CLEC4D | c.245A>T p.N82I | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by muse, mutect2
- CNTN2 | c.763C>A p.Q255K | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CPED1 | c.892C>G p.P298A | Missense Mutation (SNP) | VAF 148/299 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- CROCC | c.227T>A p.L76Q | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CSMD1 | c.10513T>G p.F3505V (on ENST00000520002; = p.F3504V on NM_033225.6) | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- DSC3 | c.2530C>A p.P844T | Missense Mutation (SNP) | VAF 142/413 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ENTPD7 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 22/194 reads (11%) | called by muse, mutect2, varscan2
- FANCM | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 64/417 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.13302_13303delinsT p.H4435Tfs*59 | Frame Shift Del (DEL) | VAF 20/135 reads (15%) | called by pindel, varscan2*
- FLOT1 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- FZD4 | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA1 | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 32/492 reads (7%) | called by muse, mutect2
- GPRIN3 | c.697A>T p.R233W | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- GRIN2A | c.2513A>G p.E838G | Missense Mutation (SNP) | VAF 12/379 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- HECW2 | c.53A>T p.Q18L | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HK2 | c.1834G>T p.D612Y | Missense Mutation (SNP) | VAF 185/517 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGFN1 | c.1001G>T p.S334I | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- IRF2BP2 | c.41A>T p.Q14L | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ITLN2 | c.620G>C p.R207T | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL34 | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL38 | c.998G>T p.S333I | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAMC2 | c.167G>T p.C56F | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MACF1 | c.13624C>T p.Q4542* (on ENST00000372915; = p.Q2475* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 87/369 reads (24%) | called by muse, mutect2, varscan2
- MAP10 | c.2732G>T p.G911V | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MCOLN2 | c.77G>T p.R26I | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MGAM | c.3533A>G p.E1178G | Missense Mutation (SNP) | VAF 49/640 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- MGAM2 | c.6176del p.P2059Lfs*34 | Frame Shift Del (DEL) | VAF 316/880 reads (36%) | called by mutect2, pindel, varscan2
- MX2 | c.367G>T p.V123F | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAA25 | c.1747C>G p.Q583E | Missense Mutation (SNP) | VAF 8/215 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.754); called by muse, mutect2
- NCF4 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR14A2 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 86/480 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.356); called by muse, varscan2
- OR2T4 | c.815C>A p.T272N | Missense Mutation (SNP) | VAF 166/776 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OTUD5 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OVCH1 | c.2831C>T p.A944V | Missense Mutation (SNP) | VAF 99/369 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PARP6 | c.1862G>T p.R621L | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PCDHB11 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 123/589 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDS5B | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 120/317 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PHIP | c.3318-1G>A p.X1106_splice | Splice Site (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- PSPC1 | c.1157A>C p.N386T | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2
- RYR2 | c.9464T>A p.L3155* | Nonsense Mutation (SNP) | VAF 131/498 reads (26%) | called by muse, mutect2, varscan2
- SLC25A42 | c.644A>C p.H215P | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SLC38A3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC38A9 | c.805A>T p.M269L | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC8A3 | c.791A>T p.K264M | Missense Mutation (SNP) | VAF 17/466 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SMPX | c.221A>T p.Q74L | Missense Mutation (SNP) | VAF 226/455 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); called by muse, varscan2
- SPATA6 | c.168T>A p.N56K | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SUCO | c.3402C>A p.D1134E | Missense Mutation (SNP) | VAF 16/483 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.01); called by muse, mutect2
- SULT1B1 | c.857C>A p.S286Y | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TACC3 | c.1855G>T p.G619C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, varscan2
- TAF2 | c.1566G>T p.W522C | Missense Mutation (SNP) | VAF 98/693 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBXT | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TCF20 | c.5599C>G p.L1867V | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, varscan2
- TLE4 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 19/280 reads (7%) | called by muse, mutect2
- TLL2 | c.1789G>C p.G597R | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM63B | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TNRC6C | c.1207T>A p.S403T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- TTN | c.97437G>C p.Q32479H (on ENST00000591111; = p.Q25055H on NM_003319.4) | Missense Mutation (SNP) | VAF 43/352 reads (12%) | PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UGT1A7 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 83/603 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- USP9Y | c.1214T>G p.L405R | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- VGLL1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ZFHX4 | c.2936A>T p.E979V | Missense Mutation (SNP) | VAF 18/674 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZFP57 | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF12 | c.1945A>T p.T649S (on ENST00000405858 / NM_016265.4; = p.T611S on NM_006956.3) | Missense Mutation (SNP) | VAF 36/659 reads (5%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF644 | c.3832G>T p.E1278* (on ENST00000337393 / NM_201269.3; = p.E56* on NM_016620.3) | Nonsense Mutation (SNP) | VAF 87/368 reads (24%) | called by muse, mutect2, varscan2
- ZNF644 | c.3831G>T p.Q1277H (on ENST00000337393 / NM_201269.3; = p.Q55H on NM_016620.3) | Missense Mutation (SNP) | VAF 89/373 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF705G | c.834C>A p.H278Q | Missense Mutation (SNP) | VAF 25/554 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2
- ZNF804B | c.3946C>A p.P1316T | Missense Mutation (SNP) | VAF 189/536 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF862 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.532); called by muse, mutect2
- CATSPERE | c.1617A>G p.R539= | Silent (SNP) | VAF 66/338 reads (20%) | catalogued as rs756643256; called by muse, varscan2
- CDON | c.2427A>T p.A809= | Silent (SNP) | VAF 26/956 reads (3%) | called by muse, mutect2
- CERCAM | c.1116C>A p.L372= | Silent (SNP) | VAF 41/150 reads (27%) | called by muse, mutect2, varscan2
- CRYGA | c.387C>A p.G129= | Silent (SNP) | VAF 38/374 reads (10%) | called by muse, mutect2
- CSMD1 | c.6153C>A p.P2051= (on ENST00000520002; = p.P2050= on NM_033225.6) | Silent (SNP) | VAF 211/620 reads (34%) | catalogued as rs377629790, COSV59305521; called by muse, mutect2, varscan2
- DCSTAMP | c.513G>T p.L171= | Silent (SNP) | VAF 34/207 reads (16%) | called by muse, mutect2, varscan2
- EXO1 | c.2440C>T p.L814= | Silent (SNP) | VAF 247/862 reads (29%) | catalogued as rs1352244309; called by muse, mutect2, varscan2
- FAM131C | c.246C>A p.A82= | Silent (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- FCRLA | c.630C>A p.P210= (on ENST00000367959; = p.P187= on NM_032738.4) | Silent (SNP) | VAF 60/252 reads (24%) | called by muse, mutect2, varscan2
- GABRG2 | c.1107C>T p.V369= (on ENST00000361925 / NM_001375343.1; = p.V329= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/564 reads (13%) | catalogued as COSV62716720; called by muse, mutect2, varscan2
- GRID1 | c.2703G>T p.S901= | Silent (SNP) | VAF 121/371 reads (33%) | called by muse, mutect2, varscan2
- H2BC7 | c.309G>T p.L103= | Silent (SNP) | VAF 18/201 reads (9%) | catalogued as rs199603482, COSV61911656; called by muse, mutect2
- H3-3A | c.81C>T p.R27= | Silent (SNP) | VAF 54/342 reads (16%) | catalogued as COSV64731906, COSV64732778; called by muse, varscan2
- INA | c.444C>A p.R148= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV63976216; called by mutect2, varscan2
- KCNA4 | c.753C>A p.I251= | Silent (SNP) | VAF 20/289 reads (7%) | called by muse, mutect2
- KLHL2 | c.12G>T p.P4= | Silent (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- LDHC | c.882C>A p.V294= | Silent (SNP) | VAF 105/270 reads (39%) | called by muse, mutect2, varscan2
- MAP2 | c.4872G>A p.R1624= | Silent (SNP) | VAF 30/524 reads (6%) | catalogued as COSV52286884; called by muse, mutect2
- MYH7 | c.765A>T p.T255= | Silent (SNP) | VAF 121/437 reads (28%) | called by muse, mutect2, varscan2
- NOC2L | c.1782C>T p.G594= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as rs746715312; called by muse, mutect2, varscan2
- NPTXR | c.783C>T p.R261= | Silent (SNP) | VAF 32/218 reads (15%) | called by muse, mutect2, varscan2
- NR5A1 | c.909C>T p.S303= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs185071408; called by muse, mutect2, varscan2
- OR2T4 | c.816C>A p.T272= | Silent (SNP) | VAF 166/778 reads (21%) | catalogued as COSV63543937; called by muse, mutect2
- OR4D1 | c.639C>A p.L213= | Silent (SNP) | VAF 94/614 reads (15%) | called by muse, mutect2, varscan2
- PAQR9 | c.450C>T p.R150= | Silent (SNP) | VAF 17/222 reads (8%) | catalogued as rs542854262, COSV61417516; called by muse, mutect2
- PCYT2 | c.672G>A p.L224= | Silent (SNP) | VAF 14/99 reads (14%) | called by muse, varscan2
- PDE5A | c.750G>T p.R250= | Silent (SNP) | VAF 29/242 reads (12%) | called by muse, mutect2
- PEX5 | c.1245C>T p.N415= (on ENST00000420616; = p.N407= on NM_000319.5) | Silent (SNP) | VAF 112/280 reads (40%) | catalogued as rs138243167; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PHLPP2 | c.381A>T p.T127= | Silent (SNP) | VAF 139/357 reads (39%) | called by muse, mutect2, varscan2
- PLG | c.852C>T p.R284= | Silent (SNP) | VAF 55/457 reads (12%) | catalogued as rs760216173, COSV51982425; called by muse, mutect2, varscan2
- POMZP3 | c.18G>A p.V6= | Silent (SNP) | VAF 29/970 reads (3%) | called by muse, mutect2
- PSG4 | c.309C>A p.S103= | Silent (SNP) | VAF 88/272 reads (32%) | called by muse, mutect2, varscan2
- RNASE11 | c.168C>A p.I56= | Silent (SNP) | VAF 40/312 reads (13%) | called by muse, mutect2
- ROS1 | c.1341G>T p.V447= | Silent (SNP) | VAF 16/394 reads (4%) | called by muse, mutect2
- SPACA7 | c.198G>A p.P66= | Silent (SNP) | VAF 13/260 reads (5%) | catalogued as rs747335229, COSV52102878; called by muse, mutect2
- STRC | c.4024C>T p.L1342= | Silent (SNP) | VAF 36/665 reads (5%) | called by muse, mutect2
- SYNE1 | c.18996C>T p.L6332= (on ENST00000367255 / NM_182961.4; = p.L6261= on NM_033071.3) | Silent (SNP) | VAF 32/772 reads (4%) | called by muse, mutect2
- TACSTD2 | c.303T>C p.D101= | Silent (SNP) | VAF 40/177 reads (23%) | called by muse, mutect2, varscan2
- TERT | c.2250C>A p.A750= | Silent (SNP) | VAF 44/400 reads (11%) | catalogued as COSV57201130; called by muse, mutect2, varscan2
- UNC80 | c.1206C>A p.L402= | Silent (SNP) | VAF 25/174 reads (14%) | called by muse, mutect2, varscan2
- ZFP57 | c.1530C>A p.T510= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs772117596; called by muse, mutect2, varscan2
- ZHX3 | c.2346C>T p.L782= | Silent (SNP) | VAF 6/123 reads (5%) | called by muse, mutect2
- ZNF766 | c.417C>T p.F139= | Silent (SNP) | VAF 11/342 reads (3%) | called by muse, mutect2
- AP001007.2 | n.184G>C | RNA (SNP) | VAF 108/400 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-109+143C>A | Intron (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- ASCC3 | c.241+4855_241+4870del | Intron (DEL) | VAF 72/471 reads (15%) | called by mutect2, pindel, varscan2
- DLL3 | c.1093+32G>T | Intron (SNP) | VAF 11/46 reads (24%) | catalogued as rs1309179319; called by muse, mutect2, varscan2
- F11R | c.*6G>T | 3'UTR (SNP) | VAF 105/356 reads (29%) | called by muse, mutect2, varscan2
- FMO6P | n.906-110C>A | Intron (SNP) | VAF 58/238 reads (24%) | called by muse, mutect2, varscan2
- GREB1 | c.901+13G>T | Intron (SNP) | VAF 59/178 reads (33%) | called by muse, mutect2, varscan2
- HPGD | c.421+524G>T | Intron (SNP) | VAF 45/255 reads (18%) | called by muse, mutect2, varscan2
- MIR365A | n.47C>G | RNA (SNP) | VAF 158/458 reads (34%) | called by muse, varscan2
- NDUFV3 | c.170-4955G>A | Intron (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- PDE7A | c.-38A>T | 5'UTR (SNP) | VAF 14/72 reads (19%) | catalogued as rs1485461793; called by muse, varscan2
- PDE7B | c.83-70355G>C | Intron (SNP) | VAF 17/188 reads (9%) | catalogued as rs890112415; called by muse, mutect2
- REEP4 | c.418-102G>T | Intron (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- S1PR3 | chr9:88991078 G>A | 5'Flank (SNP) | VAF 105/356 reads (29%) | catalogued as rs768319593; called by muse, mutect2, varscan2
- TAFA5 | c.112+55182G>A | Intron (SNP) | VAF 12/102 reads (12%) | catalogued as rs758527170; called by muse, varscan2
- TMEM135 | c.*5743C>G | 3'UTR (SNP) | VAF 258/1001 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.10361-4572A>G | Intron (SNP) | VAF 20/312 reads (6%) | catalogued as rs781734188; called by muse, mutect2
- XRRA1 | c.980-58G>A | Intron (SNP) | VAF 68/382 reads (18%) | catalogued as rs928080897; called by muse, mutect2, varscan2
